Gene-level copy-number profile of tumor specimen TCGA-CV-6936-01A from TCGA case TCGA-CV-6936, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-CV-6936-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.e793f4dc-4acd-4fbf-8972-dc2e3c9cef75.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6936-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/788f09ab-5066-45c0-9e6b-4b56a8d662bc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 6,807; copy number 2: 40,049; copy number 3: 6,780; copy number 4: 2,974; copy number 5: 1,735; copy number 6: 1,217; copy number 7: 51; copy number 9: 111; copy number 10: 15; copy number 11: 11; copy number 16: 40; copy number 32: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6936-01A-11D-1910-01): tumor purity 0.62, ploidy 2.24, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–4,503,392, 3 genes: RNA5SP251, AC027251.1, AC010941.1.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,143 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–6 (broad region; genes not listed).
- chr2:96,760,902–96,986,580, 10 genes, copy number 7 (within-gene range 3–7): CNNM4, MIR3127, CNNM3-DT, CNNM3, ANKRD23, ANKRD39, SEMA4C, FAM178B, AC092636.1, Metazoa_SRP.
- chr3:93,843,764–94,131,832, 10 genes, copy number 5: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr4:178,406,695–185,535,507, 102 genes, copy number 6 (broad region; genes not listed).
- chr4:185,587,909–185,594,003, 1 gene, copy number 6: AC093797.1.
- chr7:108,470,417–108,569,666, 1 gene, copy number 32 (within-gene range 3–32): PNPLA8.
- chr7:108,554,543–118,951,259, 126 genes, copy number 6–32 (broad region; genes not listed).
- chr11:69,294,151–71,252,577, 46 genes, copy number 7–16 (within-gene range 3–16): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr11:73,264,505–73,865,133, 16 genes, copy number 7–10 (within-gene range 1–10): P2RY6, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243.
- chr16:11,927,259–13,563,388, 27 genes, copy number 5 (within-gene range 3–5): NPIPB2, TNFRSF17, UBL5P4, SNX29, AC007216.1, RPS23P6, AC007601.1, AC007601.2, AC092365.1, AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1.
- chr19:32,687,089–33,130,542, 15 genes, copy number 6: AC008736.1, NUDT19, AC008736.2, TDRD12, AC008805.1, SLC7A9, AC008805.2, RN7SKP22, CEP89, RPL31P60, FAAP24, RHPN2, AC008521.1, AC008521.2, GPATCH1.
- chr22:18,178,038–21,517,533, 185 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,707. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
